Gene-level copy-number profile of tumor specimen TCGA-78-7542-01A from TCGA case TCGA-78-7542, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 56.8 years (20,763 days).
Specimen TCGA-78-7542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1bb43ee2-7fe4-4f87-8569-e10cabec6fa4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7542-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dcc2f109-4288-4ceb-9716-d5c1252c4438

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 2,788; copy number 3: 7,036; copy number 4: 23,188; copy number 5: 10,297; copy number 6: 7,945; copy number 7: 6,873; copy number 8: 956; copy number 9: 281; copy number 10: 307; copy number 14: 55; copy number 17: 28; copy number 21: 6; copy number 25: 14; copy number 33: 4; copy number 34: 13; copy number 61: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7542-01A-21D-2062-01): tumor purity 0.35, ploidy 4.69, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 729 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,899,871–57,031,158, 79 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr7:116,672,196–117,323,152, 29 genes, copy number 21–61: MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr7:117,332,761–117,428,123, 2 genes, copy number 21: AC002465.1, ASZ1.
- chr11:65,695,552–70,207,390, 211 genes, copy number 9–34 (broad region; genes not listed).
- chr11:98,565,074–98,945,079, 3 genes, copy number 9: AP003038.1, AP003715.1, AP002428.1.
- chr11:117,015,897–122,619,274, 171 genes, copy number 9–25 (broad region; genes not listed).
- chr11:122,679,801–122,726,311, 2 genes, copy number 25: AP002762.3, AP002762.1.
- chr18:1,254,383–12,223,539, 232 genes, copy number 10–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
